Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TB, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TB-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: M Acct: Reported:
Physician(s):
Phy Location:

Clinical History

year-old man experienced a recent onset seizure and has a left facial droop. On imaging there is a mass in the medial and superior temporal lobe that extends into the insula, with mass effect and uncal herniation.

Operative Diagnoses

Benign brain neoplasm.

Operation / Specimen

A: Brain, right temporal lobe, excision biopsy

B: Brain, temporal lobe, excision biopsy

Pathologic Diagnosis

A and B. Brain, right temporal, excisional biopsies:

1. Oligodendroglioma, diffusely infiltrating.

2. MIB-1 proliferation index: 3%.

See Microscopy Description and Comment.

Comment

The sections contain portions of cerebral cortex and adjacent white matter that are diffusely and moderately infiltrated by a glial neoplastic proliferation made of rather uniform round nuclei, with some perineuronal satellitosis.

The MIB-1

proliferation index is somewhere between 1.5% and 3%. There is not mitotic activity, microvascular proliferation, or necrosis.

In this limited sample the neoplasm has a phenotype consistent with an oligodendroglial origin, and is devoid of

anaplastic features (WHO II).

Electronically Signed Out

Senior Staff Pathologist
, Senior Staff

Consultant:
Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Surgical Pathology

Page 2 of 4

Interpretation

POSITIVE: Allelic loss on chromosome arm 19q is detected.

Allelic loss on chromosome 1p is not detected.

Informative loci are: D1S548, D1S1592, D1S552, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing was performed on DNA extracted from tumor paraffin block (B1). H&E stained slide was examined and marked by a pathologist for subsequent tumor dissection. Peripheral blood DNA was used for germline

TCG-03
Oligodendroglioma, grade II
945013
Site: Brain, supratentorial
Brain, temporal lobe
C71.0
C71.2
QJ 1/22/14

[page 2 of 4]
comparison,

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing was performed on DNA extracted from tumor paraffin block (B1). H&E stained slide was examined

and marked by a pathologist for subsequent tumor dissection.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

Surgical Pathology

Page 3 of 4

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

[page 3 of 4]
was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, right temporal lobe, excision biopsy: Astrocytic proliferation, reactive, atypical; also undifferentiated cells (C/W neoplastic oligos, R/O astrocytic, non-diagnostic). 2 crush preparations and 4 touch preparations. Preparations performed at . No frozen

section slides prepared, . Slides interpreted by . at the utilizing telepathology and reported on

B. Brain, temporal lobe, excision biopsy: Brain, right temporal lobe, excision biopsy: Astrocytic proliferation, reactive, atypical, and undifferentiated cells(C/W neoplastic oligodendrocytes, R/O astrocytes, non-diagnostic). 2 crush preparations and 4 touch preparations. Preparations performed at

. No frozen section slides prepared, . Slides interpreted by at the main campus of utilizing telepathology and reported on

Staff Pathologist

, Senior Staff

Pathologist

Gross Description

A.

Brain, right temporal lobe, excision biopsy:

CONTAINER LABEL: right temporal lobe.

FIXATIVE: Formalin. NO. PIECES: num. SIZE/VOL: 13 x 10 x 4 mm. CASSETTES: 1,

B.

Brain, temporal lobe, excision biopsy:

CONTAINER LABEL: temporal lobe.

FIXATIVE: Formalin. NO. PIECES: few. SIZE/VOL: 10 x 6 x 3 mm. CASSETTES: 1,

Microscopic Description

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a gliofibrillary background throughout the specimen, and

numerous reactive astrocytes. About one fourth of neoplastic nuclei over express strongly the p53 protein. With the

MIB-1 the proliferation index of the total number of cells is about 1.5%, perhaps about 3% in the neoplasm assuming

that one half of nuclei are native non-neoplastic cells.

ICD-9(s): 225.0 225.0

Billing Fee Code(s): A:

Surgical Pathology

Page 4 of 4

B:

[page 4 of 4]
LOH 1p19q:

MGMT:

Histo Data

Part A: Brain, right temporal lobe, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

TPS Triage x 1 1

Part B: Brain, temporal lobe, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

x 1 1 For 1p, 19q LOH, microdissecti

EMA-DA x 1 1

mGFAP-DA x 1 1

H&E x 1 1

MGMT-curis x 1 1

MIB1-DA x 1 1

NeuN x 1 1

P53DO7 x 1 1

Synap-DA x 1 1

TPS Triage x 1 1

HIFAA Discrepancy		✓

Source: NCI Genomic Data Commons file 42201f72-d464-4328-952b-1120bddc7805 (TCGA-DU-A7TB.3D167AD9-276F-47F4-9C77-D7AD8B24D59F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).